CGCI case BLGSP-71-06-00253 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d04504c8-766f-4829-9d11-cc32f3052f63

Demographics
Sex at birth: male; Race: black or african american; Age at index: 8 years; Vital status: Dead; Days to death: 215 days.

Diagnoses (2)
1. Burkitt lymphoma, NOS (Includes all variants) (the primary disease): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 8.1 years (2,962 days); Year of diagnosis: 2015; Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 215 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Endemic; Max tumor bulk site: Other; Sites of involvement: Testes / Abdomen.
   Pathology details: Tumor largest dimension diameter: 8.6 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: COP; Days to treatment start: 12 days; Days to treatment end: 23 days; Number of cycles: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 12 days; Days to treatment end: 23 days; Number of cycles: 2.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Regimen or line of therapy: CHOP-21; Days to treatment start: 30 days; Days to treatment end: 141 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Treatment intent type: Adjuvant; Days to treatment start: 30 days; Days to treatment end: 141 days; Number of cycles: 6.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.
2. Tumor, NOS: Tissue or organ of origin: Bones of skull and face and associated joints; Classification of tumor: Synchronous primary; Age at diagnosis: 8.5 years (3,103 days); Days to diagnosis: 141 days.
   Recorded as not given: Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 1 day; Disease response: With Tumor.
- Follow-up contacts recording only the day: day 141, day 215.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 762 [Blood test normal range upper: 340].

Other clinical attributes
- Day 0: Weight: 25 kg; Height: 85 cm; BMI: 34.6.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00253-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Needle Biopsy; Tissue collection type: Prospective.
- Sample BLGSP-71-06-00253-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00253-01-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-06-00253-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-06-00253-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Days from index date to last known alive: 1; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Extranodal involvment other: Scrotum, Abdominal masses; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Tru-cut biopsy; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 762; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form 2: New tumor event diagnosis indicator: Yes.
- Follow-up form 2, New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Right maxillary mass; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 2.
- Treatments, Treatment 2: Chemo end reporting period: Yes; Pharma adjuvant cycles count: 6.
